TCGA case TCGA-UD-AAC4 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Western Australia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2b740646-7cd4-4c7f-890a-7b3db6ebc1b8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 65 years; Vital status: Dead; Days to death: 719 days (2.0 years).

Diagnoses (5)
1. Mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9050/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.6 years (23,949 days); Year of diagnosis: 2004; Method of diagnosis: Cytology; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 719 days (2.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine; Days to treatment start: 308 days; Days to treatment end: 462 days (1.3 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sunitinib Malate; Days to treatment start: 608 days (1.7 years); Days to treatment end: 651 days (1.8 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Days to treatment start: 693 days (1.9 years); Days to treatment end: 693 days (1.9 years); Treatment outcome: Progressive Disease.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Progression of diagnosis 1 (Mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 66.3 years (24,216 days); Days to diagnosis: 267 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Progression of diagnosis 1 (Mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 67.1 years (24,504 days); Days to diagnosis: 555 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Mesothelioma, malignant), site: Vertebral column. Age at diagnosis: 67.5 years (24,651 days); Days to diagnosis: 702 days (1.9 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 267 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 267 days.
- Day 555 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 555 days (1.5 years).
- Day 702 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vertebral column; Days to progression: 702 days (1.9 years).
- Days to follow up: 719 days (2.0 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- ECOG performance status: 3; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 0.837 mg/dL [Blood test normal range lower: 0.803; Blood test normal range upper: 1.301].
- Serum Mesothelin 1.3 nmol/L [Blood test normal range lower: 0.3; Blood test normal range upper: 2.5].

Exposures
- Exposure type: Asbestos; Age at last exposure: 21; Age at onset: 16; Exposure duration years: 5.
- Occupation duration years: 42; Occupation type: Physical and Engineering Science Technicians.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UD-AAC4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 490 mg.
  Slide TCGA-UD-AAC4-01A-01-TSA: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 17; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UD-AAC4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UD-AAC4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Asbestos exposure years: 05; Primary occupation: Other, please specify; Occupation primary: Draughting manager; Performance status timing: Pre-Adjuvant Therapy.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Diffuse malignant mesothelioma - NOS; Serum mesothelin prior treatment: 1.302.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Sutent; Treatment best response: Clinical Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Skin; Other malignancy histological type: Melanoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision of lesions.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 719 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 719 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 267 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UD-AAC4-01A-11D-A39Q-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.
